Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A0LF, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A0LF-01A (Primary Tumor).

[page 1 of 2]
TSS Name/#.

1CB-0-3

Specimens Submitted:

- 1: SP: Gallbladder
- 2: SP: Omental nodule (
- 3: SP: Uterus, cervix, bilateral tubes ovaries
- 4: SP: Left external iliac lymph nodes
- 5: SP: Left obturator lymph nodes
- 6: SP: Left hypogastric lymph node
- 7: SP: Right obturator lymph nodes
- 8: SP: Right hypogastric lymph nodes
- 9: SP: Left common iliac lymph nodes (
- 10: SP: Left para-aortic lymph nodes
- 11: SP: Omentum (
- 12: SP: Right common iliac lymph nodes
- 13: SP: Right para-aortic lymph nodes

adenocarcinoma, endometrioid, Nos 8380/3

Site: Endometrium C54.1

hw 5/1/11

DIAGNOSIS:

- 1) GALLBLADDER; CHOLECYSTECTOMY:
- CHOLECYSTITIS AND CALCIFICATION OF THE WALL.
- 2) OMENTAL NODULE; EXCISION:
- METASTATIC CARCINOMA.
- 3) UTERUS, CERVIX, OVARIES AND FALLOPIAN TUBES; HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE WITH CLEAR CELL FEATURES.
- FIGO GRADE III (> 50% SOLID GROWTH), NUCLEAR GRADE 3.
- THE TUMOR INVADES TO < HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 2 MM. -
THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 12 MM.
- ENDOCERVICAL INVASION IS PRESENT BOTH IN THE MUCOSA AND THE STROMA.
- THE ENDOMETRIUM SHOWS ATROPHY.
- THE MYOMETRIUM IS UNREMARKABLE.
- THE LEFT OVARY SHOWS METASTATIC CARCINOMA.

NOTE: SELECTED SLIDES HAVE BEEN REVIEWED WITH DR. [REDACTED]

- 4) LYMPH NODE, LEFT EXTERNAL ILIAC; EXCISION:
- THREE OUT OF SIX LYMPH NODES, POSITIVE FOR METASTATIC

** Continued on next page **

hw 5/1/11

[page 2 of 2]
----- Page 2 of 6
CARCINOMA (3/6).

- 5) LYMPH NODE, LEFT OBTURATOR; EXCISION:
- FIVE OUT OF ELEVEN LYMPH NODES, POSITIVE FOR METASTATIC
CARCINOMA (5/11).
- 6) LYMPH NODE, HYPOGASTRIC; EXCISION:
- TWO OUT OF TWO LYMPH NODES, POSITIVE FOR METASTATIC
CARCINOMA (2/2).
- 7) LYMPH NODE, RIGHT OBTURATOR; EXCISION:
- TWO OUT OF EIGHT LYMPH NODES, POSITIVE FOR METASTATIC
CARCINOMA (2/8).
- 8) LYMPH NODES, RIGHT HYPOGASTRIC; EXCISION:
- TWO OUT OF FOUR LYMPH NODES, POSITIVE FOR METASTATIC
CARCINOMA. (2/4)
- 9) LYMPH NODE, LEFT COMMON ILIAC; EXCISION:
- ONE NEGATIVE LYMPH NODE (0/1).
- 10) LYMPH NODES, LEFT PARA-AORTIC; EXCISION:
- EIGHT NEGATIVE LYMPH NODES (0/8).
- 11) OMENTUM; EXCISION:
- NEGATIVE FOR TUMOR.
- 12) LYMPH NODE, RIGHT COMMON ILIAC; EXCISION:
- FATTY TISSUE.
- 13) LYMPH NODE, PARA-AORTIC; EXCISION:
- TWO NEGATIVE LYMPH NODES (0/2).

*** Report Electronically Signed Out ***

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION
OF THE SLIDES (AND/OR OTHER
MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file 2be8fb72-dc4e-427c-8964-5d8148398094 (TCGA-AP-A0LF.7112CE75-9EFD-4989-9F2A-4D0F517B8EDE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).